Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5K0, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5K0-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 1
SEX: F
ADM DATE:

UID:4ESC6CF0-F346-4ECE-B296-0D2B4513804

PAT TYPE:

OPER DATE:

PROCEDURE: SPHS

Patient was hospitalized in _____ for a hypertensive episode as well as hypokalemia. A CT showed a left adrenal mass measuring 6.2 x 4.0 cm. She states she is currently easily fatigued. Clinical Diagnosis: Left adrenal mass. Operative Procedure/Tissue Submitted: Left open adrenalectomy.

PROCEDURE: SPGD

1. "Left adrenal gland." Received in formalin in a medium container is a 105 gram, excisional specimen of a nodular gray-tan adrenal gland with a thin rim of surrounding periadrenal fat, measuring 9 x 6.8 x 4.3 cm. The specimen has been previously inked blue and sectioned for tissue procurement. No orientation is given. The remainder of specimen is inked blue, specimen is serially sectioned to reveal a diffusely pink-gray, soft, nodular mass, with smooth cut surface, arising from within a yellow/partially cystic adrenal, with majority of lesion outside, and a residual of normal yellow adrenal, 3.0 cm on one edge of mass. The periadrenal fat appears to be not involved. The lesion is, otherwise, well-circumscribed with a thin, clear membrane overlying. The specimen is submitted as follows:

- 1A. Normal adrenal to tumor.
- 1B. Cystically dilated area of adrenal, involved with lesion.
- 1C. Representative section of the mass.
- 1D. Additional sections of mass.
- 1E. Additional cystically dilated adrenal.
- 1F. Additional tumor to adrenal and periadrenal adipose tissue.
- 1ADDA-1ADDDG. Additional sections of tumor to capsule.
- (NOTE: 1E-1G. Thin membrane of capsule slips and might not be represented).

PROCEDURE: SPMI

ADRENOCORTICAL CARCINOMA

Tumor Size: 9 x 6.3 x 4.3 cm.
Tumor Weight: 105 grams.
Capsular Invasion: Present focally.
Vascular Invasion: Negative.
Surgical Margins: Close.

ICD-O-3

Carcinoma, adrenal cortical 8370/3
Site: Adrenal Gland, Cortex C74.0
Q10 1/26/13

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

BIRTHDATE:

PAGE #: 2

SEX: F

ADM DATE:

PAT TYPE:

OPER DATE:

Necrosis: Present.

Mitotic Rate: 8 / 50.

Grade: Low.

Lymph node status: N.A.

Extra-adrenal Extension: Negative.

Stage: pT2NxMx

Number of fields reviewed: 25.

Mitotic figures: 4

PROCEDURE: SPDX

1. Left adrenal gland, resection: Adrenocortical carcinoma. Capsule invasion is present focally, with margins close.

The signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Diagnosis Synchrony		
Case is (first):		

12/22/12

12/13

Source: NCI Genomic Data Commons file 9dfbca21-a1b2-474e-8357-17d7fc76b07d (TCGA-OR-A5K0.4E5C6CF0-F346-4ECE-B296-0D2DB4513804.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).